Somatic mutation profile of tumor specimen C3L-00640-01 (aliquot CPT0064520010_1) from CPTAC case C3L-00640, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.3 years (21,667 days).
Specimen C3L-00640-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1bef304-0b24-4966-965e-8b8f3e6457bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00640-31 (Blood Derived Normal), aliquot CPT0066660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0ffe128-f7f5-470f-b495-f8013467c093

The open-access MAF lists 57 somatic variants for this specimen: 29 protein-altering or splice-affecting, 20 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 20, Intron 3, 3'UTR 3, 3'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 38/592 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 58/648 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CAMK1D | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1160339552, COSV101123382, COSV66618326; called by muse, mutect2
- CLIC3 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 67/597 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV65406421; called by muse, mutect2, varscan2
- COL18A1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs899510965; called by muse, mutect2
- GRIN3B | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760582633; called by muse, mutect2, varscan2
- ISM2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754380719, COSV53636434; called by muse, mutect2, varscan2
- KCNB2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV73050758; called by muse, mutect2, varscan2
- KCNK3 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 49/528 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs1185578898, COSV57191531; called by muse, mutect2
- KIF21B | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 62/856 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs746619358; called by muse, mutect2
- MYO10 | c.3928G>A p.A1310T | Missense Mutation (SNP) | VAF 57/585 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs751350671; called by muse, mutect2, varscan2
- OR5AP2 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 33/379 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756963104, COSV57257858; called by muse, mutect2
- RBM5 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 44/483 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as rs1559698584, COSV61737053; called by muse, mutect2
- RPL3L | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139587023, COSV51907144; called by muse, mutect2
- SCUBE2 | c.2620C>T p.R874C (on ENST00000649792 / NM_001367977.2; = p.R817C on NM_020974.3) | Missense Mutation (SNP) | VAF 83/668 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289340109, COSV58548458; called by muse, mutect2, varscan2
- SYP | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 100/617 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs782810430, COSV54295798; called by muse, mutect2, varscan2
- ZNF536 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs905189576, COSV62819778; called by muse, mutect2
- ABCA1 | c.1250A>T p.E417V | Missense Mutation (SNP) | VAF 53/387 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- CALML5 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 83/675 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FAM71C | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 74/734 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- GPR143 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- HNRNPF | c.748A>C p.S250R | Missense Mutation (SNP) | VAF 75/951 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2
- PLXNA2 | c.2596G>T p.V866L | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- SLCO5A1 | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 22/339 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); called by muse, mutect2
- SLIRP | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SMAD4 | c.1075_1076dup p.D360Efs*25 | Frame Shift Ins (INS) | VAF 28/268 reads (10%) | called by mutect2, pindel
- SOX30 | c.1523T>C p.L508P | Missense Mutation (SNP) | VAF 69/546 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF215 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF385D | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- A2ML1 | c.4023G>A p.P1341= | Silent (SNP) | VAF 15/163 reads (9%) | catalogued as rs751414888, COSV100229160; called by muse, mutect2
- ACACA | c.2763A>C p.R921= | Silent (SNP) | VAF 33/429 reads (8%) | called by muse, mutect2
- ADGRG2 | c.2034C>A p.V678= (on ENST00000379869 / NM_001079858.3; = p.V675= on NM_005756.4) | Silent (SNP) | VAF 47/588 reads (8%) | called by muse, mutect2
- BICRA | c.1686G>A p.A562= | Silent (SNP) | VAF 21/235 reads (9%) | catalogued as rs765461994; called by muse, mutect2
- C1orf105 | c.489A>T p.L163= | Silent (SNP) | VAF 26/378 reads (7%) | called by muse, mutect2
- COL6A3 | c.5112C>T p.D1704= | Silent (SNP) | VAF 74/975 reads (8%) | catalogued as rs759756382, COSV55080190; ClinVar: likely benign; called by muse, mutect2
- EYS | c.5823T>C p.N1941= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, varscan2
- GLYATL2 | c.390C>A p.T130= | Silent (SNP) | VAF 18/203 reads (9%) | called by muse, mutect2
- IL36RN | c.84T>C p.A28= | Silent (SNP) | VAF 76/888 reads (9%) | called by muse, mutect2
- KIAA0825 | c.1143G>A p.E381= | Silent (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2, varscan2
- LIPE | c.2655C>T p.S885= | Silent (SNP) | VAF 20/260 reads (8%) | catalogued as rs149909979, COSV54925191; ClinVar: likely benign; called by muse, mutect2
- MAP1A | c.6096C>T p.T2032= | Silent (SNP) | VAF 68/754 reads (9%) | called by muse, mutect2
- PADI4 | c.1419C>T p.D473= | Silent (SNP) | VAF 53/486 reads (11%) | catalogued as rs765538193; called by muse, mutect2, varscan2
- PLEKHF1 | c.90G>A p.A30= | Silent (SNP) | VAF 44/336 reads (13%) | called by muse, mutect2, varscan2
- S1PR5 | c.471G>A p.A157= | Silent (SNP) | VAF 63/630 reads (10%) | called by muse, mutect2
- SLC6A3 | c.1305C>T p.I435= | Silent (SNP) | VAF 96/875 reads (11%) | catalogued as rs760545154; called by muse, mutect2, varscan2
- THRAP3 | c.876G>A p.G292= | Silent (SNP) | VAF 28/316 reads (9%) | catalogued as rs768748683; called by muse, mutect2
- TPSG1 | c.138C>T p.A46= | Silent (SNP) | VAF 66/541 reads (12%) | catalogued as rs779284702; called by muse, mutect2, varscan2
- TSPAN14 | c.726C>T p.A242= | Silent (SNP) | VAF 28/485 reads (6%) | called by muse, mutect2
- ZNF423 | c.3120G>A p.T1040= (on ENST00000563137 / NM_001379286.1; = p.T1032= on NM_015069.4) | Silent (SNP) | VAF 27/220 reads (12%) | catalogued as rs145829157, COSV52189873; called by muse, mutect2, varscan2
- EYA1 | c.273-61C>T | Intron (SNP) | VAF 55/499 reads (11%) | catalogued as rs770463075; called by muse, mutect2, varscan2
- FANCC | c.1329+140G>A | Intron (SNP) | VAF 32/342 reads (9%) | called by muse, mutect2
- H2BP2 | chr1:143876264 C>T | 3'Flank (SNP) | VAF 55/1604 reads (3%) | called by muse, mutect2
- HOXA11 | c.*21G>A | 3'UTR (SNP) | VAF 82/927 reads (9%) | catalogued as rs765082062; called by muse, mutect2
- MAML3 | c.468+18647C>T | Intron (SNP) | VAF 23/319 reads (7%) | called by muse, mutect2
- PABPN1L | c.*91C>T | 3'UTR (SNP) | VAF 27/366 reads (7%) | catalogued as rs917940734, COSV56352114; called by muse, mutect2
- TBC1D3P2 | n.662T>C | RNA (SNP) | VAF 52/978 reads (5%) | called by muse, mutect2
- VAPB | c.*359G>A | 3'UTR (SNP) | VAF 54/548 reads (10%) | catalogued as rs562368880; called by muse, mutect2, varscan2
